Somatic mutation profile of tumor specimen MMRF_1579_1_BM_CD138pos (aliquot MMRF_1579_1_BM_CD138pos_T1_KBS5U_L03509) from MMRF case MMRF_1579, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.0 years (24,840 days).
Specimen MMRF_1579_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48f694dd-e68c-408b-bc8a-06464cb34505.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1579_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1579_1_PB_Whole_C2_KBS5U_L03513; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/590c776b-5ef2-4aeb-a91b-e4b7dbb0d9e9

The open-access MAF lists 204 somatic variants for this specimen: 76 protein-altering or splice-affecting, 25 silent, 103 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, 3'UTR 52, Silent 25, Intron 22, 5'UTR 9, RNA 8, 5'Flank 7, Nonsense Mutation 7, Splice Site 5, 3'Flank 5, Splice Region 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 84/280 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP12 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs765782081, COSV53584311; called by muse, mutect2
- ASXL2 | c.3532G>A p.E1178K | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as COSV55458513, COSV99711169; called by muse, mutect2, varscan2
- CACHD1 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs751845549, COSV51557912; called by muse, mutect2
- CTNNA2 | c.1075G>T p.G359* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as COSV58151365, COSV58154909; called by muse, mutect2, varscan2
- DCDC1 | c.1877+2T>G p.X626_splice | Splice Site (SNP) | VAF 54/111 reads (49%) | catalogued as rs1228468176, COSV100663950; called by muse, mutect2, varscan2
- DST | c.10861C>T p.R3621C | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs753976937, COSV55022810; called by muse, mutect2, varscan2
- ELMO2 | c.596G>A p.S199N | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.599); catalogued as rs1373602909; called by muse, mutect2
- FAT4 | c.3413C>A p.S1138Y | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.506); catalogued as COSV101272516, COSV67893400; called by muse, mutect2, varscan2
- FRMPD2 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV59723525; called by muse, mutect2, varscan2
- H2AC12 | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV63617442; called by muse, mutect2, varscan2
- IGLV3-1 | c.344A>G p.H115R | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.423); catalogued as rs753612185; called by muse, mutect2, varscan2
- JMJD6 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs374399276; called by muse, mutect2
- MSH6 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs1064795094, COSV99315568; ClinVar: uncertain significance; called by muse, mutect2
- NIPSNAP3B | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.335); catalogued as COSV66106708; called by muse, mutect2, varscan2
- NRK | c.4741G>A p.D1581N | Missense Mutation (SNP) | VAF 10/283 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV54606746, COSV99689108; called by muse, mutect2
- NRXN3 | c.809C>T p.T270M (on ENST00000557594 / NM_001272020.2; = p.T902M on NM_004796.6) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs746669604, COSV55322053; called by muse, mutect2, varscan2
- NUP210 | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.631); catalogued as rs1359017333, COSV99596459; called by muse, mutect2, varscan2
- OBSCN | c.4279C>T p.Q1427* | Nonsense Mutation (SNP) | VAF 27/118 reads (23%) | catalogued as rs373130742; called by muse, mutect2, varscan2
- PCDHA8 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as COSV100969362; called by muse, mutect2, varscan2
- PLIN3 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs751566130; called by muse, mutect2, varscan2
- PLPPR2 | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV52260483; called by muse, mutect2
- POT1 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs868501952; called by muse, mutect2, varscan2
- PRICKLE3 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.195); catalogued as rs928124183; called by muse, mutect2, varscan2
- RP1 | c.5238G>A p.W1746* | Nonsense Mutation (SNP) | VAF 58/157 reads (37%) | catalogued as COSV99078555; called by muse, mutect2, varscan2
- RPAP2 | c.985A>G p.I329V | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT tolerated (0.91); PolyPhen benign (0.018); catalogued as rs765093281; called by muse, mutect2, varscan2
- SEMA6B | c.1153T>G p.Y385D | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56705292; called by muse, mutect2, varscan2
- SEMA6D | c.2956G>A p.G986S (on ENST00000316364 / NM_153618.2; = p.G924S on NM_020858.2) | Missense Mutation (SNP) | VAF 177/420 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.241); catalogued as rs777740416; called by muse, mutect2, varscan2
- SETX | c.5547_5548+2del p.X1849_splice | Splice Site (DEL) | VAF 32/108 reads (30%) | catalogued as rs1554813128; called by pindel, varscan2
- SLC22A14 | c.1687C>T p.R563* | Nonsense Mutation (SNP) | VAF 13/161 reads (8%) | catalogued as rs770289592; called by muse, mutect2
- TEAD1 | c.330+1G>T p.X110_splice | Splice Site (SNP) | VAF 48/246 reads (20%) | catalogued as COSV100532382; called by muse, mutect2, varscan2
- TNN | c.2858T>C p.V953A | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV53438266; called by muse, mutect2
- USP34 | c.4154T>G p.L1385R | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.691); catalogued as rs1166250140; called by muse, mutect2, varscan2
- WAS | c.1453+8G>A | Splice Region (SNP) | VAF 12/114 reads (11%) | catalogued as rs782559657; called by muse, mutect2, varscan2
- ZNF831 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs767830319, COSV64038794; called by muse, mutect2, varscan2
- ACY1 | c.1002-6C>T | Splice Region (SNP) | VAF 33/125 reads (26%) | called by muse, mutect2, varscan2
- ARHGAP10 | c.1361C>T p.T454I | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- B3GALNT2 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 6/168 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.718); called by muse, mutect2
- CACNA1A | c.3926G>T p.G1309V | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC168 | c.12512C>T p.P4171L | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); called by muse, mutect2
- CFAP126 | c.116_119dup p.Q40Hfs*63 | Frame Shift Ins (INS) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- DNHD1 | c.4531G>T p.V1511L | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DUSP10 | c.1345C>T p.L449F | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- ECPAS | c.1705C>G p.P569A | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- FAM214A | c.1256G>A p.G419E | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GGCX | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GPR179 | c.5816A>T p.D1939V (on ENST00000621958; = p.D1938V on NM_001004334.4) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HEATR1 | c.3563+1G>T p.X1188_splice | Splice Site (SNP) | VAF 22/244 reads (9%) | called by muse, mutect2
- KERA | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- LAMA2 | c.9266G>T p.R3089I | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- LAMB4 | c.1887+1G>A p.X629_splice | Splice Site (SNP) | VAF 37/215 reads (17%) | called by muse, mutect2, varscan2
- LBX2 | c.332C>T p.A111V (on ENST00000377566 / NM_001282430.2; = p.A107V on NM_001009812.2) | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- LRATD1 | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- MAGEE2 | c.752T>A p.F251Y | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2
- MED14 | c.3607C>T p.L1203F | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- NEDD4 | c.2708A>T p.H903L (on ENST00000508342 / NM_001284338.1; = p.H484L on NM_006154.4) | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2
- NUP37 | c.868C>G p.P290A | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OAZ3 | c.127A>C p.I43L | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2
- PDE2A | c.2630T>C p.L877P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- POLR1C | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PRRC2A | c.1987del p.Q663Sfs*23 | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | called by mutect2, pindel, varscan2
- RCAN3 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- RCAN3 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by mutect2, varscan2
- SBF2 | c.108G>A p.W36* | Nonsense Mutation (SNP) | VAF 90/263 reads (34%) | called by muse, mutect2, varscan2
- SMARCD2 | c.911del p.L304Rfs*72 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- SNX1 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 78/160 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SPATA7 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TACC2 | c.7651T>A p.F2551I (on ENST00000334433; = p.F629I on NM_006997.4) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TTN | c.26698T>C p.S8900P (on ENST00000591111; = p.S7973P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/97 reads (10%) | PolyPhen benign (0.062); called by muse, varscan2
- UQCRC1 | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, varscan2
- VBP1 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- VEGFC | c.194G>T p.S65I | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZMYND8 | c.634G>C p.A212P (on ENST00000311275 / NM_001363741.2; = p.A232P on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF484 | c.737C>G p.T246S | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- ZNF544 | c.2054_2080del p.E685_C693del | In Frame Del (DEL) | VAF 24/94 reads (26%) | called by mutect2, pindel, varscan2
- ZNF641 | c.1122C>A p.C374* | Nonsense Mutation (SNP) | VAF 8/123 reads (7%) | called by muse, mutect2
- ANKUB1 | c.1341C>T p.P447= | Silent (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- B3GALNT2 | c.948C>T p.I316= | Silent (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- C1QTNF4 | c.297C>T p.D99= | Silent (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.507C>T p.V169= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs769619622, COSV101444544, COSV70507554; called by muse, mutect2, varscan2
- FAM193A | c.2400C>T p.G800= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV61191664, COSV61199082; called by muse, mutect2, varscan2
- FOXJ2 | c.258G>A p.K86= | Silent (SNP) | VAF 35/203 reads (17%) | catalogued as COSV50818237; called by muse, mutect2, varscan2
- GPR149 | c.348C>T p.G116= | Silent (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- HIVEP2 | c.2469G>A p.V823= | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- IGKV5-2 | c.267A>G p.T89= | Silent (SNP) | VAF 38/92 reads (41%) | catalogued as rs1203975126; called by muse, varscan2
- IL1RAPL1 | c.1020T>C p.N340= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as COSV56250447; called by muse, mutect2, varscan2
- LAMA1 | c.9177G>A p.A3059= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs149807552; called by muse, mutect2, varscan2
- MALRD1 | c.3858G>A p.V1286= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs1230157567; called by muse, mutect2, varscan2
- MORN5 | c.141C>T p.Y47= | Silent (SNP) | VAF 25/168 reads (15%) | called by muse, mutect2, varscan2
- NFKBIE | c.414G>A p.A138= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1309495571; called by muse, mutect2, varscan2
- NLGN1 | c.1959C>T p.A653= | Silent (SNP) | VAF 27/250 reads (11%) | catalogued as COSV64337491; called by muse, mutect2
- NUDT2 | c.339C>T p.A113= | Silent (SNP) | VAF 34/133 reads (26%) | called by muse, mutect2, varscan2
- NYX | c.1329C>T p.S443= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs1449375033, COSV100699364, COSV61180292; called by muse, mutect2, varscan2
- OR5AS1 | c.300A>G p.Q100= | Silent (SNP) | VAF 96/196 reads (49%) | catalogued as rs1353771163; called by muse, mutect2, varscan2
- RNF150 | c.306C>T p.C102= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SALL3 | c.1674C>G p.P558= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs1465821131, COSV73306383; called by muse, mutect2, varscan2
- SHROOM3 | c.2850G>A p.A950= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs1319986434; called by muse, mutect2, varscan2
- SS18L1 | c.63C>T p.I21= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs753748572; called by muse, mutect2
- TAF1L | c.1555T>C p.L519= | Silent (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
- TBC1D2 | c.474C>T p.A158= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs1240408297; called by muse, mutect2, varscan2
- UGT2B11 | c.420A>G p.L140= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as rs1420425892; called by muse, mutect2
- AC079612.1 | n.1202C>G | RNA (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- AC103993.1 | n.1046G>A | RNA (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.243-71C>T | Intron (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- AL772337.1 | n.867G>T | RNA (SNP) | VAF 39/177 reads (22%) | catalogued as rs200487737; called by muse, mutect2, varscan2
- ANK3 | c.12596-435G>A | Intron (SNP) | VAF 14/101 reads (14%) | catalogued as rs778947009; called by muse, mutect2, varscan2
- ARMC10P1 | n.728C>A | RNA (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- BBX | c.*2183T>G | 3'UTR (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- CCDC40 | c.*376G>C | 3'UTR (SNP) | VAF 71/132 reads (54%) | called by muse, mutect2, varscan2
- CCDC68 | chr18:54903375 A>G | 3'Flank (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- CCNT2 | c.*1242A>T | 3'UTR (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- CCNT2 | c.*1243G>T | 3'UTR (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- CEMIP | chr15:80952967 A>C | 3'Flank (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- CEP162 | c.*660G>A | 3'UTR (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- COL4A3 | c.*2766C>G | 3'UTR (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- CRTAM | c.194-79C>T | Intron (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- CST9 | c.*1087C>T | 3'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- DMD | c.2292+766G>C | Intron (SNP) | VAF 33/144 reads (23%) | called by muse, mutect2
- DNAJC10 | c.*1242G>A | 3'UTR (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- DOP1A | c.*97A>T | 3'UTR (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- EIF3IP1 | n.658C>T | RNA (SNP) | VAF 29/76 reads (38%) | catalogued as rs995742029; called by muse, mutect2, varscan2
- ESRRG | c.*1295A>C | 3'UTR (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- ESRRG | c.*266C>T | 3'UTR (SNP) | VAF 113/230 reads (49%) | called by muse, mutect2, varscan2
- FAM102A | c.*44G>A | 3'UTR (SNP) | VAF 104/434 reads (24%) | called by muse, mutect2, varscan2
- FAM199X | c.*2834G>A | 3'UTR (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- FBXO38 | c.*574dup | 3'UTR (INS) | VAF 44/114 reads (39%) | catalogued as rs1006756191; called by mutect2, varscan2
- FBXO41 | c.*1309C>A | 3'UTR (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- FCER1A | c.*286C>T | 3'UTR (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- FLRT2 | c.*688C>T | 3'UTR (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- FSTL1 | c.*1325C>G | 3'UTR (SNP) | VAF 24/328 reads (7%) | called by muse, mutect2
- GABRA2 | c.1059+975dup | Intron (INS) | VAF 8/84 reads (10%) | called by mutect2, pindel
- GAL3ST3 | c.-112-22_-112-20del | Intron (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- GET1 | c.*491G>A | 3'UTR (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2, varscan2
- GKN1 | c.-34C>A | 5'UTR (SNP) | VAF 150/397 reads (38%) | called by muse, mutect2, varscan2
- GPRIN3 | c.*1984G>A | 3'UTR (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- GPS1 | c.33+438_33+448del | Intron (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- GVINP1 | n.4030A>G | RNA (SNP) | VAF 12/251 reads (5%) | called by muse, mutect2
- HDGF | c.*295T>G | 3'UTR (SNP) | VAF 7/177 reads (4%) | called by muse, mutect2
- HILPDA | chr7:128455867 G>A | 5'Flank (SNP) | VAF 31/66 reads (47%) | catalogued as rs1346100151; called by muse, mutect2
- HMGCLL1 | c.632+201A>G | Intron (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- HOOK2 | c.1641-225G>A | Intron (SNP) | VAF 109/449 reads (24%) | called by muse, mutect2, varscan2
- IGLL5 | c.-101G>A | 5'UTR (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2
- IGLL5 | c.-99G>A | 5'UTR (SNP) | VAF 32/60 reads (53%) | catalogued as rs192387679, COSV73249145; called by muse, mutect2
- IL17RA | c.*37G>A | 3'UTR (SNP) | VAF 66/148 reads (45%) | catalogued as COSV100083419; called by muse, varscan2
- IL17RA | c.*134G>A | 3'UTR (SNP) | VAF 36/78 reads (46%) | called by muse, varscan2
- INO80D | c.*7309A>C | 3'UTR (SNP) | VAF 9/106 reads (8%) | called by muse, mutect2
- IRS2 | c.*939A>C | 3'UTR (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- JMJD4 | c.961-41C>T | Intron (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- KLHL21 | c.1501-54G>T | Intron (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2, varscan2
- LCK | c.1042-39C>T | Intron (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- LIMS1 | chr2:108684146 G>T | 3'Flank (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- LMBR1L | c.157+364C>A | Intron (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2
- LRP5L | n.885G>A | RNA (SNP) | VAF 63/137 reads (46%) | catalogued as COSV101292791; called by muse, mutect2, varscan2
- MEIS2 | c.-777G>A | 5'UTR (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- MIR30C2 | chr6:71377148 G>C | 5'Flank (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- MOCS2 | c.*236G>A | 3'UTR (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- Metazoa_SRP | chr10:77969816 C>G | 3'Flank (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- NIPAL1 | c.*2404C>G | 3'UTR (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- NOX5 | c.*8T>A | 3'UTR (SNP) | VAF 64/200 reads (32%) | called by muse, mutect2, varscan2
- NRIR | chr2:6840660 G>T | 5'Flank (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- NTNG2 | c.*2175G>T | 3'UTR (SNP) | VAF 16/42 reads (38%) | called by mutect2, varscan2
- NTRK3 | c.2133+12867C>A | Intron (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- OR9K2 | c.-26C>A | 5'UTR (SNP) | VAF 25/354 reads (7%) | called by muse, mutect2
- ORAI2 | c.*6652C>T | 3'UTR (SNP) | VAF 39/123 reads (32%) | catalogued as rs1235284089; called by muse, mutect2, varscan2
- PAX4 | c.14-26T>A | Intron (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- PAX7 | c.-185C>G | 5'UTR (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- PCYOX1 | c.*2745A>C | 3'UTR (SNP) | VAF 38/69 reads (55%) | catalogued as rs554375839; called by muse, mutect2, varscan2
- PDAP1 | c.*52T>G | 3'UTR (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- PDPN | chr1:13583754 C>T | 5'Flank (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- PDXK | c.*2274C>A | 3'UTR (SNP) | VAF 4/96 reads (4%) | called by muse, mutect2
- PPP1R17 | c.*415T>C | 3'UTR (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- PRDM16 | chr1:3067619 G>A | 5'Flank (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2
- PRKCG | c.-287G>A | 5'UTR (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2, varscan2
- PTGDS | c.-24G>A | 5'UTR (SNP) | VAF 21/81 reads (26%) | catalogued as rs781284020; called by muse, mutect2, varscan2
- PTGR1 | c.651+1053C>T | Intron (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- PYROXD2 | c.*229G>A | 3'UTR (SNP) | VAF 49/105 reads (47%) | called by mutect2, varscan2
- RAB11FIP2 | c.*1965C>T | 3'UTR (SNP) | VAF 64/114 reads (56%) | called by muse, mutect2, varscan2
- RAD23B | c.66+1060C>T | Intron (SNP) | VAF 116/378 reads (31%) | catalogued as rs1034130161; called by muse, mutect2, varscan2
- RARRES2P7 | n.403G>A | RNA (SNP) | VAF 4/49 reads (8%) | catalogued as rs1186227362; called by muse, mutect2
- RCAN3 | c.*195G>T | 3'UTR (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- RMND5B | c.*749C>G | 3'UTR (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- RNF170 | chr8:42850403 G>A | 3'Flank (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- RNU6-307P | chr1:174993891 T>A | 5'Flank (SNP) | VAF 36/112 reads (32%) | called by muse, mutect2, varscan2
- RPS3 | c.351-148G>A | Intron (SNP) | VAF 5/84 reads (6%) | catalogued as rs1223292855, COSV53705433; called by muse, mutect2
- SALL1 | c.*9G>A | 3'UTR (SNP) | VAF 47/205 reads (23%) | catalogued as rs753566942, COSV99183578; called by muse, mutect2, varscan2
- SEMA5A | c.*7601C>A | 3'UTR (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- SGK3 | c.742-162G>T | Intron (SNP) | VAF 24/60 reads (40%) | catalogued as rs889293542; called by muse, varscan2
- SLC26A8 | chr6:36024800 G>A | 5'Flank (SNP) | VAF 40/133 reads (30%) | called by muse, mutect2, varscan2
- SLC6A9 | c.1654+33C>T | Intron (SNP) | VAF 66/135 reads (49%) | catalogued as rs200442118; called by muse, mutect2, varscan2
- SMC5 | c.*445G>A | 3'UTR (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- SOX17 | c.*728C>A | 3'UTR (SNP) | VAF 27/107 reads (25%) | called by muse, mutect2, varscan2
- SPATC1L | c.-547T>C | 5'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2, varscan2
- SPRY3 | c.*6706G>T | 3'UTR (SNP) | VAF 35/464 reads (8%) | called by muse, mutect2
- SPRYD7 | c.*835C>T | 3'UTR (SNP) | VAF 5/88 reads (6%) | catalogued as rs1339406951; called by muse, mutect2
- SSH3 | c.66+45C>G | Intron (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- TBL1X | c.*3032C>T | 3'UTR (SNP) | VAF 15/92 reads (16%) | catalogued as rs62581874; called by muse, mutect2, varscan2
- THRA | c.1111-134G>C | Intron (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- TMEM151A | c.*149G>A | 3'UTR (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- TMEM151B | c.*1087G>A | 3'UTR (SNP) | VAF 17/47 reads (36%) | catalogued as rs924885692, COSV65255902; called by muse, mutect2, varscan2
- TMEM192 | c.*3461A>G | 3'UTR (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- TRIB2 | c.*900T>C | 3'UTR (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- WDFY1 | c.*588C>T | 3'UTR (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- YRDC | c.*146A>G | 3'UTR (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.*20C>T | 3'UTR (SNP) | VAF 15/107 reads (14%) | catalogued as rs1450733668; called by muse, mutect2, varscan2
